Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BZ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

ICD-6-3
Leiomyosarcoma 8890/3
Site Buttock NOS 049.5
JW 11/22/13

....

Clinical Diagnosis & History:

Right buttock fungating mass incisional biopsy leiomyosarcoma

Specimens Submitted:

- 1: Right buttock mass
- 2: New inferior, medial margin
- 3: Superior margin

DIAGNOSIS:

1. Soft tissue, right buttock, mass; radiacal excision:
- Pleomorphic Leiomyosarcoma, high grade.
- Tumor measures 8.0 cm in greatest dimension.
- Tumor involves superficial soft tissue with focal extension to the underlying skeletal muscle.
- Tumor ulcerates the skin surface.
- Multiple satellite nodules of tumor are noted adjacent to the main mass.
- Resection margins are uninvolved; closest margin deep (clearance 0.1 cm).
2. Soft tissue, right buttock, new inferior medial margin; excision:
- Fibroadipose tissue, negative for malignancy.
3. Soft tissue, right buttock, superior margin; excision:
- Microscopic nodules of Pleomorphic Leiomyosarcoma involving adipose tissue.
- Tumor extends to the cauterized and inked margin.

Note: The prior material [REDACTED] was reviewed.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2

Gross Description:

1) Received fresh, labeled "right buttocks mass" is a 15x10.5x4.5 cm oriented skin with attached soft tissue mass. The tan mass is located 1.5 cm from the skin surface. The tan skin measures 14.5x8.5 cm. The specimen is inked as follows: superior=blue, inferior=green, medial=orange, lateral=yellow, deep=black. The specimen is serially sectioned to reveal an 8x7x6cm ill-defined tan lobulated mass with hemorrhage and about 10% necrosis, 0.6 cm from inferior margin, 1.5 cm from superior margin, 2cm from medial margin, 1.8 cm from lateral margin, 0.3 cm from deep margin. A portion of the tissue is submitted to TPS. Gross photos are taken. The specimen is representatively submitted.

Summary of sections:

SM superior margin
IM-inferior margin
MM medial margin
LM- lateral margin
DM- deep margin
T- tumor
LN- possible lymph nodes

2) Received fresh, labeled "new inferior, medial margin" is a 2.5x2x0.5 oriented fibroadipose tissue with a stitch marking the true margin which is inked blue. The specimen is serially sectioned and entirely submitted.

Summary of sections:

U entire

3) Received fresh, labeled "superior margin" is a 4x3x0.6 cm oriented fibroadipose tissue with a stitch marking the true margin which is inked blue. The specimen is serially sectioned and entirely submitted.

Summary of sections:

U entire

Summary of Sections:

Part 1: Right buttock mass
Part 2: New inferior, medial margin
Part 3: Superior margin

** End of Report **

Source: NCI Genomic Data Commons file 47066c9f-6ee4-4ab9-b9bc-721c5a9cdcca (TCGA-DX-A8BZ.AA7CE39D-D3CC-4481-A762-0FBED90A22F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).